Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5976, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5976-01A (Primary Tumor).

[page 1 of 4]
DIAGNOSIS

- (A) LEVEL I "A" MIDLINE:
Four lymph nodes, no tumor present (0/4).
- (B) LEFT NECK DISSECTION, LEVEL I "B":
METASTATIC SQUAMOUS CARCINOMA IN ONE OF SEVEN LYMPH NODES WITH EXTRANODAL EXTENSION (1/7).
Salivary gland, no tumor present.
- (C) LEFT LINGUAL NERVE:
INVASIVE SQUAMOUS CARCINOMA IN SOFT TISSUE.
- (D) LEFT HYPOGLOSSAL NERVE:
Nerve and skeletal muscle, no tumor present.
- (E) LEFT HEMIGLOSSECTOMY:
DEEPLY INVASIVE SQUAMOUS CARCINOMA, MODERATE TO POORLY DIFFERENTIATED (6.5 CM).
PERINEURAL INVASION IDENTIFIED.
- (F) VENTRAL TONGUE:
Squamous mucosa, no tumor present.
- (G) RIGHT FLOOR OF MOUTH:
Squamous mucosa and minor salivary gland, no tumor present.
- (H) ANTERIOR DORSAL TONGUE:
Squamous mucosa and skeletal muscle, no tumor present.
- (I) POSTERIOR DORSAL TONGUE:
Squamous mucosa and skeletal muscle, no tumor present.
- (J) LEFT RETROMOLAR TRIGONE:
Squamous mucosa and skeletal muscle, no tumor present.
- (K) BASE OF TONGUE:
Squamous mucosa, no tumor present.
- (L) LEFT GINGIVA:
Squamous mucosa, no tumor present.
- (M) RIGHT GINGIVA:
Fibrovascular tissue, no tumor present.
- (N) LEFT LINGUAL NERVE:
SQUAMOUS CARCINOMA IN SOFT TISSUE.
- (O) LEFT NECK DISSECTION, LEVEL II:
METASTATIC SQUAMOUS CARCINOMA IN ONE OF TWO LYMPH NODES WITH EXTRANODAL EXTENSION (1/2).
- (P) LEFT NECK DISSECTION, LEVEL III:
Ten lymph nodes, no tumor present (0/10).
- (Q) LEFT NECK DISSECTION, LEVEL IV:
Nine lymph nodes, no tumor present (0/9).
- (R) LEFT LINGUAL NERVE:
Nerve, no tumor present.
- (S) RIGHT NECK DISSECTION, LEVEL I:
Four lymph nodes, no tumor present (0/4).
Salivary gland, no tumor present.

[page 2 of 4]
- (T) RIGHT NECK DISSECTION, LEVEL II:
Five lymph nodes, no tumor present (0/5).
- (U) RIGHT NECK DISSECTION, LEVEL III:
Seven lymph nodes, no tumor present (0/7).
- (V) RIGHT MAXILLA:
Fibrovascular tissue with chronic inflammation, no tumor present.
- (W) TEETH:
Teeth (gross only).
- (X) LYMPH NODE, LEFT FACIAL ARTERY:
One lymph node, no tumor present (0/1).

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

(A) LEVEL I "A" MIDLINE - Fibroadipose tissue, 2.5 x 1.0 x 1.0 cm. Six possible lymph nodes are identified, ranging from 0.2 x 0.2 x 0.2 cm to 1.0 x 0.4 x 0.3 cm.

SECTION CODE: A1, five possible lymph nodes; A2, one lymph node bisected. [REDACTED]

(B) LEFT NECK DISSECTION LEVEL I "B" - A salivary gland, 3.0 x 2.0 x 1.5 cm, and fibroadipose tissue, 3.5 x 2.5 x 1.5 cm. Cut surface displays unremarkable salivary gland. Seven lymph nodes are identified, ranging from 0.4 x 0.3 x 0.3 cm to 1.8 x 1.2 x 0.9 cm.

SECTION CODE: B1, representative section of salivary gland; B2, five lymph nodes; B3, one lymph node serially sectioned; B4, one lymph node serially sectioned. [REDACTED]

(C) LEFT LINGUAL NERVE - Received is a piece of nerve with attached fibroadipose tissue (0.6 x 0.5 x 0.3 cm). The specimen is submitted entirely for frozen section.

SECTION CODE: C, left lingual nerve, entirely submitted for frozen section. [REDACTED]

*FS/DX: INVASIVE CARCINOMA. [REDACTED]

(D) LEFT HYPOGLOSSAL NERVE - A segment of nerve measuring 0.8 cm in length and 0.3 cm in diameter. The specimen is sectioned and submitted entirely for frozen section diagnosis. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(E) LEFT HEMIGLOSSECTOMY - A 9.5 x 6.5 x 2.5 cm. There is a lesion (6.5 x 5.5 x 2.0 cm). The resection margins are grossly free of tumor. The tumor is sampled and representative sections are submitted in E1-E16, from anterior to posterior. [REDACTED]

(F) VENTRAL TONGUE, NEW MARGIN INKED - A piece of fleshy red soft tissue (2.2 x 0.3 x 0.3 cm). The specimen is inked at one side. The specimen is submitted entirely for frozen section diagnosis, ink side down. [REDACTED]

*FS/DX: NO TUMOR PRESENT [REDACTED]

(G) RIGHT FLOOR OF MOUTH, NEW MARGIN INKED - A piece of tan-pink soft tissue (1.2 x 0.5 x 0.3 cm). The specimen is inked at the new margin. The specimen is submitted entirely for frozen section diagnosis, ink down. [REDACTED]

*FS/DX: NO TUMOR PRESENT [REDACTED]

(H) ANTERIOR DORSAL TONGUE, NEW MARGIN INKED - A piece of tan-pink soft tissue (3.2 x 0.7 x 0.3 cm). The specimen is inked at one surface. The specimen is entirely submitted for frozen section diagnosis, ink down. [REDACTED]

[page 3 of 4]
*FS/DX: NO TUMOR PRESENT. [REDACTED]

(I) POSTERIOR DORSAL TONGUE, NEW MARGIN INKED - A piece of tan-pink soft tissue (3.6 x 0.5 x 0.5 cm). The specimen is inked at one surface. The specimen is entirely submitted for frozen section diagnosis, ink down, [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(J) LEFT RETROMOLAR TRIGONE, NEW MARGIN INKED - A piece of tan-pink soft tissue measuring (2.6 x 0.7 x 0.6 cm). The specimen is inked at one surface. The specimen is submitted entirely for frozen section diagnosis, ink down, [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(K) BASE OF TONGUE, NEW MARGIN INKED - A piece of fleshy red soft tissue measuring (2.4 x 0.6 x 0.6 cm). The specimen is entirely submitted for frozen section diagnosis, ink down, [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(L) LEFT GINGIVA, NEW MARGIN INKED - A piece of tan-pink soft tissue (2.6 x 0.3 x 0.3 cm). The specimen is submitted entirely for frozen section diagnosis, ink down, [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(M) RIGHT GINGIVA, NEW MARGIN INKED - A piece of tan-pink soft tissue (0.7 x 0.3 x 0.3 cm). The specimen is submitted entirely for frozen section diagnosis, ink down, [REDACTED]

*FS/DX: ALMOST NO EPITHELIUM, NO TUMOR PRESENT. [REDACTED]

(N) LEFT LINGUAL NERVE, PROXIMAL MARGIN INKED - A segment of nerve with surrounding soft tissue, measuring (0.6 x 0.4 x 0.3 cm). The specimen is entirely submitted for frozen section diagnosis, ink on edge, [REDACTED]

*FS/DX: SQUAMOUS CELL CARCINOMA EXTREMELY CLOSE TO THE NERVE. [REDACTED]

(O) LEFT NECK DISSECTION LEVEL II - Fibroadipose tissue, 4.5 x 2.0 x 1.6 cm. Two lymph nodes (1.0 x 0.8 x 0.8 cm and 2.5 x 1.5 x 1.5 cm) are identified and entirely submitted.

SECTION CODE: O1, one lymph node serially sectioned; O2 and O3, one lymph node serially sectioned. [REDACTED]

(P) LEFT NECK DISSECTION LEVEL III - Fibroadipose tissue, 4.0 x 2.0 x 1.0 cm. Ten lymph nodes are identified, ranging from 0.2 x 0.2 x 0.2 cm to 1.6 x 1.0 x 0.7 cm.

SECTION CODE: P1, two lymph nodes; P2, five lymph nodes; P3-P5, each containing one lymph node serially sectioned. [REDACTED]

(Q) LEFT NECK DISSECTION LEVEL IV - Fibroadipose tissue, 3.5 x 2.0 x 1.0 cm. Nine lymph nodes are identified, ranging from 0.2 x 0.2 x 0.2 cm to 1.3 x 0.7 x 0.4 cm.

SECTION CODE: Q1, five lymph nodes; Q2, three lymph nodes; Q3, one lymph node serially sectioned. [REDACTED]

(R) LEFT LINGUAL NERVE, PROXIMAL MARGIN INKED - Received is a segment of nerve (1.3 x 0.5 x 0.4 cm). The proximal margin is previously inked. The specimen is bisected and submitted entirely for frozen section.

INK CODE: Blue - previously inked proximal margin.

SECTION CODE: R, left lingual nerve, longitudinally bisected (perpendicular to margin), entirely submitted for frozen section. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(S) RIGHT NECK DISSECTION LEVEL I - A fragment of red-tan tissue (4.3 x 3.5 x 1.4 cm) consisting of a tan, homogeneous unremarkable gland (3.2 x 2.4 x 1.1 cm) and five tan-pink lymph nodes (2.4 x 1.3 x 1.1 cm).

SECTION CODE: S1, S2, representative sections of the gland; S3, S4, one lymph node, serially sectioned, four parts; S5, one lymph node, serially sectioned, four parts; S6, one lymph node bisected; S7, two lymph nodes [REDACTED]

(T) RIGHT NECK DISSECTION LEVEL II - A fragment of red to yellow-tan tissue (4.5 x 2.8 x 1.7 cm). Eight possible lymph nodes (2.3 x 1.8 x 1.1 cm to 0.2 x 0.2 x 0.1 cm).

SECTION CODE: T1, T2, T3, one lymph node, serially sectioned in six parts; T4, one lymph node, serially sectioned in four parts; T5, one lymph node, trisected; T6, one lymph node, bisected; T7, four possible lymph nodes. [REDACTED]

(U) RIGHT NECK DISSECTION LEVEL III - A fragment of yellow-tan tissue (4.2 x 3.8 x 1.0 cm). Seven possible lymph nodes (1.6 x 0.8 x 0.5 cm to 0.2 x 0.1 x 0.1 cm).

[page 4 of 4]
SECTION CODE: U1, one lymph node, serially sectioned, five parts; U2, one lymph node, bisected; U3, one lymph node, bisected; U4, four possible lymph nodes. [REDACTED]
(V) RIGHT MAXILLA - A tan-pink nonoriented irregular fragment of tissue (1.0 x 0.5 x 0.2 cm). Toto in V. [REDACTED]
(W) TEETH (GROSS ONLY) - Multiple teeth in fragments ranging in size from 0.6 x 0.4 x 0.2 to 2.0 x 1.0 x 1.0 cm. The specimen is entirely submitted for gross only. [REDACTED]
(X) LYMPH NODE, LEFT FACIAL ARTERY - A single lymph node (0.6 x 0.4 x 0.3 cm). Toto in X. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-53000, M-80703

Some tests reported here may have been developed and performance characteristics determined by [REDACTED] Pathology and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration.

Released by: [REDACTED]

Source: NCI Genomic Data Commons file b76083e5-89cf-4bfe-8bba-7d6c6da3abf2 (TCGA-CV-5976.5CA063D0-5232-4EA4-BEA3-39F8143D7771.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).